Gene-level copy-number profile of tumor specimen C3N-03783-01 from CPTAC case C3N-03783, project CPTAC-3 (Gum — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Gum, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 67.1 years (24,500 days).
Specimen C3N-03783-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Alveolar Ridge; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4c6a5b46-4fdb-40f3-b4f9-1f5d96e03686.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03783-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/d9b7a0d1-dd45-4219-9afc-ca0adbaf2078

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 391; copy number 1: 1,500; copy number 2: 38,265; copy number 3: 14,869; copy number 4: 3,340; copy number 5: 232; copy number 6: 12; copy number 7: 25; copy number 8: 65; copy number 9: 20; copy number 11: 35; copy number 12: 1; copy number 14: 38; copy number 15: 17; copy number 17: 3; copy number 19: 14; copy number 20: 13; copy number 23: 5; copy number 27: 5; copy number 28: 11; copy number 29: 1; copy number 34: 33; copy number 37: 3; copy number 42: 13.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,498,785–143,500,512, 2 genes: AC239859.2, LINC02799.
- chr1:143,619,994–143,620,527, 1 gene (within-gene range 0–1): PFN1P12.
- chr1:143,811,359–143,825,837, 1 gene: AC239798.1.
- chr1:143,929,994–144,373,659, 11 genes (within-gene range 0–1): RPL22P5, FAM72C, SRGAP2D, IGKV1OR1-1, AC244015.1, AC244015.2, LINC02802, RNA5SP529, DRD5P2, AC245595.1, PPIAL4E.
- chr9:61,581,813–61,582,675, 1 gene: AL935212.3.
- chr9:61,642,383–61,666,386, 3 genes: Y_RNA, AL935212.1, AL935212.2.
- chr9:136,114,581–136,124,363, 2 genes: TMEM250, AL138781.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 546 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:33,502,072–33,522,230, 2 genes, copy number 6: TOMM40P3, AC034232.1.
- chr8:49,740,216–51,809,445, 13 genes, copy number 5–12: PSAT1P1, AC113145.1, AC023762.1, SNTG1, AC090539.1, AC090539.2, CYCSP22, AC087272.1, AC090919.1, AC012413.1, PXDNL, BRIX1P1, BTF3P1.
- chr10:101,354,033–101,557,321, 1 gene, copy number 6 (within-gene range 3–6): BTRC.
- chr11:38,498,995–40,112,599, 9 genes, copy number 6: AC021713.1, LINC02759, LINC01493, AC021723.2, AC021723.1, RNU6-99P, AC021749.1, AC021820.1, AC080100.1.
- chr11:43,311,963–45,825,258, 65 genes, copy number 5 (broad region; genes not listed).
- chr12:45,014,672–46,004,685, 19 genes, copy number 5–11: DBX2, AC008127.1, RACGAP1P1, SSBL3P, RNA5SP361, PLEKHA8P1, AC009248.1, ANO6, AC009248.2, AC063924.1, AC079950.1, U6, AC008124.1, ARID2, AC009464.1, RN7SL246P, KNOP1P2, SCAF11, AC084878.1.
- chr12:66,275,940–72,728,844, 116 genes, copy number 9–42 (broad region; genes not listed).
- chr14:54,938,949–58,648,321, 82 genes, copy number 5 (broad region; genes not listed).
- chr14:58,794,654–58,828,176, 2 genes, copy number 5: AL049873.1, AL049873.2.
- chr22:16,897,445–21,551,461, 237 genes, copy number 5–23 (within-gene range 2–23) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 382. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
